Somatic mutation profile of tumor specimen C3L-03374-01 (aliquot CPT0240150006) from CPTAC case C3L-03374, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 82.9 years (30,274 days).
Specimen C3L-03374-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbe7a66f-1cf1-48eb-a5a2-68b3d6f18c0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03374-31 (Blood Derived Normal), aliquot CPT0240600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/218f3ead-2245-45ff-8d04-2a26086efd48

The open-access MAF lists 619 somatic variants for this specimen: 394 protein-altering or splice-affecting, 202 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 368, Silent 202, Nonsense Mutation 20, Intron 9, 3'UTR 5, 5'Flank 4, Splice Region 4, 5'UTR 2, RNA 2, Splice Site 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 204/350 reads (58%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- NF1 | c.2953C>T p.Q985* | Nonsense Mutation (SNP) | VAF 185/284 reads (65%) | catalogued as rs1555614455, CS1311518, COSV62202063; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 272/390 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.2917C>T p.P973S (on ENST00000326724 / NM_001080395.3; = p.P870S on NM_004920.2) | Missense Mutation (SNP) | VAF 225/372 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as rs1490368392; called by muse, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 152/400 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABI3 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 260/365 reads (71%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV56800378; called by muse, mutect2, varscan2
- ACADSB | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 89/149 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs761098384, COSV62550483; called by muse, mutect2, varscan2
- ADAM20 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 123/467 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as rs746283662; called by muse, mutect2, varscan2
- ADCY6 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 121/523 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs371582738; called by muse, mutect2, varscan2
- AFF2 | c.2699C>T p.S900L | Missense Mutation (SNP) | VAF 78/114 reads (68%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1557288178; called by muse, mutect2, varscan2
- AKAP6 | c.4697C>T p.S1566L | Missense Mutation (SNP) | VAF 162/395 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55229446; called by muse, mutect2, varscan2
- ALG13 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 189/255 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1251785247; called by muse, mutect2, varscan2
- ALPG | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs770792158; called by muse, mutect2
- AMY1A | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 173/695 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1399426942; called by muse, mutect2, varscan2
- ARAP2 | c.4883G>A p.R1628Q | Missense Mutation (SNP) | VAF 165/301 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.223); catalogued as rs771641324, COSV58281935, COSV58289114; called by muse, mutect2, varscan2
- ARHGEF10L | c.3674C>T p.P1225L | Missense Mutation (SNP) | VAF 328/509 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV51430469; called by muse, mutect2, varscan2
- ASXL3 | c.5303G>A p.R1768K | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV52456258; called by muse, mutect2, varscan2
- ATP2A3 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 112/475 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.203); catalogued as rs373653499; called by muse, mutect2, varscan2
- BBOX1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 137/262 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779597028, COSV54191977, COSV99589911; called by muse, mutect2
- CACNA1S | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 261/382 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV62939603; called by muse, mutect2, varscan2
- CAPN11 | c.1681-1G>A p.X561_splice | Splice Site (SNP) | VAF 136/374 reads (36%) | catalogued as COSV67239473; called by muse, mutect2, varscan2
- CASKIN1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV58872264; called by muse, mutect2, varscan2
- CCDC153 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 146/285 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV64310890; called by muse, mutect2, varscan2
- CCDC88C | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 221/601 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771732363; called by muse, mutect2, varscan2
- CEMIP | c.3392G>A p.W1131* | Nonsense Mutation (SNP) | VAF 136/343 reads (40%) | catalogued as COSV54989626; called by muse, mutect2, varscan2
- CFH | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 157/237 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs761698279, COSV62776388; called by muse, mutect2, varscan2
- CKAP2L | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs376164527; called by muse, mutect2, varscan2
- CLVS1 | c.922G>C p.V308L | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.1); catalogued as COSV57971112; called by muse, mutect2, varscan2
- CNGB3 | c.1972C>A p.P658T | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV60698825; called by muse, mutect2, varscan2
- COL13A1 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 211/385 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV62572167; called by muse, mutect2, varscan2
- COL3A1 | c.3118C>T p.P1040S | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.997); catalogued as COSV58582845; called by muse, mutect2, varscan2
- CPED1 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 106/329 reads (32%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.84); catalogued as COSV60008926; called by muse, mutect2, varscan2
- CPXM1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 172/404 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66045082; called by muse, mutect2, varscan2
- CTR9 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 117/228 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63728181; called by muse, mutect2, varscan2
- CYP11B2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 192/443 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750090886, COSV59994448; called by muse, mutect2, varscan2
- DNAH5 | c.9286C>T p.R3096* | Nonsense Mutation (SNP) | VAF 146/450 reads (32%) | catalogued as rs868444911, CM147994, COSV54213734; called by muse, varscan2
- DNAH7 | c.7627G>A p.D2543N | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56770074; called by muse, mutect2, varscan2
- DNAH7 | c.3997G>A p.G1333R | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56790905; called by muse, mutect2, varscan2
- DNASE1L3 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as rs770698995, COSV59157310; called by muse, mutect2
- DNTT | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 138/242 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV64523460, COSV64523781; called by muse, mutect2, varscan2
- DOCK11 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 106/148 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs755463907, COSV52243585; called by muse, mutect2, varscan2
- DSP | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV65792824; called by muse, mutect2, varscan2
- EPB41L1 | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 175/433 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1569330507; called by muse, mutect2, varscan2
- EPPIN | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 98/337 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV60548693; called by muse, mutect2, varscan2
- ESYT3 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56679808; called by muse, mutect2, varscan2
- FAM135B | c.3506G>A p.G1169E | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52712378; called by muse, mutect2, varscan2
- FAM135B | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52716164, COSV52717595; called by muse, mutect2, varscan2
- FAN1 | c.2902A>G p.S968G | Missense Mutation (SNP) | VAF 104/402 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as rs767657658; called by muse, mutect2, varscan2
- FAT2 | c.10405G>A p.G3469R | Missense Mutation (SNP) | VAF 143/289 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV55820988; called by muse, mutect2, varscan2
- FAT3 | c.9376G>A p.D3126N | Missense Mutation (SNP) | VAF 141/264 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53101471; called by muse, mutect2, varscan2
- FBLN1 | c.2034G>A p.M678I | Missense Mutation (SNP) | VAF 185/472 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs764937908; called by muse, mutect2, varscan2
- FBXO46 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 172/411 reads (42%) | catalogued as COSV100480236, COSV58348441; called by muse, mutect2, varscan2
- FGF4 | c.575G>C p.R192P | Missense Mutation (SNP) | VAF 245/1916 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51449397; called by muse, mutect2, varscan2
- GABRA2 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 119/215 reads (55%) | catalogued as rs748381199; called by muse, mutect2, varscan2
- GADL1 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs138172857, COSV99244274; called by muse, mutect2, varscan2
- GARS1 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 79/418 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV66829301; called by muse, mutect2, varscan2
- GPR137B | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV63991401, COSV99053742; called by muse, mutect2, varscan2
- GRB14 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs771953822, COSV99814701; called by muse, mutect2, varscan2
- GRHPR | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 233/344 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as rs566239341, COSV58942080; called by muse, mutect2, varscan2
- GRM8 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 124/461 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.461); catalogued as COSV58807935; called by muse, mutect2, varscan2
- HCFC1 | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 135/188 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV60074064; called by muse, mutect2, varscan2
- HEATR1 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 267/374 reads (71%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs1325581869; called by muse, mutect2, varscan2
- HIF3A | c.1573C>T p.R525W (on ENST00000377670 / NM_152795.4; = p.R456W on NM_022462.4) | Missense Mutation (SNP) | VAF 231/507 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs148799051; called by muse, mutect2, varscan2
- HTR4 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58796555; called by muse, mutect2, varscan2
- HTR7 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 204/337 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV53291580; called by muse, mutect2, varscan2
- HYDIN | c.15271C>T p.P5091S | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1398658334; called by muse, mutect2, varscan2
- IDO2 | c.97C>T p.L33= (on ENST00000389060; = p.L46= on NM_194294.2) | Splice Region (SNP) | VAF 93/227 reads (41%) | catalogued as rs1177723478, COSV58427186, COSV58427889; called by muse, mutect2, varscan2
- IL1R2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.088); catalogued as rs1475404272; called by muse, mutect2, varscan2
- IL21R | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs1220183340; called by muse, mutect2, varscan2
- INMT | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 134/497 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs140032041; called by muse, mutect2, varscan2
- IQCB1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1227278986; called by muse, mutect2, varscan2
- KAT14 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 196/542 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs760685954, COSV100890062; called by muse, mutect2, varscan2
- KCNH5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs754436628, COSV59753363; called by muse, mutect2, varscan2
- KCNH5 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 132/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604016, COSV59767610; called by muse, mutect2, varscan2
- KIF7 | c.3835C>T p.R1279C | Missense Mutation (SNP) | VAF 113/537 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749221779, COSV51543159; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHDC7A | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 344/537 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV68770218; called by muse, mutect2, varscan2
- KRT6B | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 95/746 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52884893; called by muse, mutect2
- KSR2 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 185/392 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.208); catalogued as COSV56683662; called by muse, mutect2, varscan2
- LAMA2 | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as rs765699885; called by muse, mutect2, varscan2
- LILRB2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 134/394 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.748); catalogued as rs746485626, COSV58745250; called by muse, mutect2, varscan2
- LIPI | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100753876; called by muse, mutect2, varscan2
- LMBR1L | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 137/311 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs140140427; called by muse, mutect2, varscan2
- LMOD3 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 234/484 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101342023; called by muse, mutect2, varscan2
- LRP2 | c.12728G>A p.R4243Q | Missense Mutation (SNP) | VAF 154/313 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs375149200; called by muse, mutect2, varscan2
- LTF | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 195/438 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs780336244; called by muse, mutect2, varscan2
- MAG | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as rs1286617721; called by muse, mutect2, varscan2
- MAGI1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 95/432 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs756986553, COSV58338153; called by muse, mutect2, varscan2
- MAML3 | c.2751G>C p.Q917H | Missense Mutation (SNP) | VAF 13/370 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1424435653; called by muse, mutect2
- MAP7D3 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750693264; called by muse, mutect2, varscan2
- MECOM | c.745G>A p.G249R (on ENST00000468789 / NM_001105078.4; = p.G437R on NM_004991.4) | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99245736; called by muse, mutect2, varscan2
- MKI67 | c.3394C>T p.P1132S | Missense Mutation (SNP) | VAF 132/254 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.28); catalogued as COSV64074241; called by muse, mutect2, varscan2
- MMP1 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 325/591 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV59510428; called by muse, mutect2, varscan2
- MORN5 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 117/184 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65649147, COSV65649670; called by muse, mutect2, varscan2
- MUC16 | c.34652C>T p.P11551L | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs754738066; called by muse, mutect2, varscan2
- MUC16 | c.34027G>A p.E11343K | Missense Mutation (SNP) | VAF 78/376 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.093); catalogued as COSV67455859; called by muse, mutect2, varscan2
- MUC16 | c.7636C>T p.L2546F | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV67476361; called by muse, mutect2, varscan2
- MUC16 | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 126/274 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs779487752, COSV67486912; called by muse, mutect2, varscan2
- MUC17 | c.6026C>T p.P2009L | Missense Mutation (SNP) | VAF 115/394 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs780828762; called by muse, mutect2, varscan2
- MYOM1 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV55289814; called by muse, mutect2, varscan2
- NAT10 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 77/664 reads (12%) | catalogued as COSV57662424, COSV57663753; called by muse, mutect2, varscan2
- NCAPH2 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs767460003; called by muse, mutect2, varscan2
- NCOA6 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs868576757, COSV62868252; called by muse, mutect2, varscan2
- NDN | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 156/374 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV59359363; called by muse, mutect2, varscan2
- NEB | c.13393G>A p.G4465S | Missense Mutation (SNP) | VAF 92/189 reads (49%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.999); catalogued as rs1239862833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEU4 | c.274G>A p.D92N (on ENST00000391969 / NM_001167602.3; = p.D104N on NM_080741.4) | Missense Mutation (SNP) | VAF 79/552 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747131201; called by muse, mutect2, varscan2
- NLRP12 | c.2996C>A p.T999N | Missense Mutation (SNP) | VAF 93/413 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs779333916; called by muse, mutect2, varscan2
- NLRP13 | c.2537G>A p.G846E | Missense Mutation (SNP) | VAF 144/344 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100738108; called by muse, mutect2, varscan2
- NLRP4 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 108/221 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV56723100; called by muse, mutect2, varscan2
- NMS | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV65258785, COSV65259340; called by muse, mutect2, varscan2
- NOBOX | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199538689, COSV56197973; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOVA1 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 135/384 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57472961; called by muse, mutect2, varscan2
- NUP188 | c.2221C>T p.H741Y | Missense Mutation (SNP) | VAF 136/247 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65362411; called by muse, mutect2, varscan2
- NXNL2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 155/336 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.411); catalogued as rs748931914, COSV65474242; called by muse, mutect2, varscan2
- OR10J3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 666/840 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59954348; called by muse, mutect2, varscan2
- OR1E2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 275/426 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV50265889; called by muse, mutect2, varscan2
- OR4M1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 187/521 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV100271081; called by muse, mutect2, varscan2
- OR52E2 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs267602936, COSV58611784; called by muse, mutect2
- OR5L2 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 124/228 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV65724970; called by muse, mutect2, varscan2
- OR6V1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 133/569 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769060424, COSV101389239; called by muse, mutect2, varscan2
- P2RX6 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 175/460 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53036635; called by muse, mutect2, varscan2
- PAGE5 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 184/264 reads (70%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs750510595, COSV56944675; called by muse, mutect2, varscan2
- PCDHA3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 180/302 reads (60%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.15); catalogued as rs1406650011, COSV63539881; called by muse, mutect2
- PCDHB7 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 122/217 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.158); catalogued as COSV50796391; called by muse, mutect2, varscan2
- PCDHB9 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 299/486 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); catalogued as rs1385267477; called by muse, mutect2, varscan2
- PCLO | c.11868G>A p.M3956I | Missense Mutation (SNP) | VAF 126/317 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.194); catalogued as COSV100430745; called by muse, mutect2, varscan2
- PCNX3 | c.4621C>T p.R1541C | Missense Mutation (SNP) | VAF 181/299 reads (61%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.985); catalogued as rs765339856; called by muse, mutect2, varscan2
- PEBP1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 140/356 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as rs11554101, COSV54337642; called by muse, varscan2
- PGPEP1L | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs1193248631; called by muse, mutect2, varscan2
- PGR | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs766277966, COSV54797179; called by muse, mutect2, varscan2
- PJA1 | c.1138C>T p.R380* (on ENST00000361478 / NM_145119.4; = p.R192* on NM_022368.5) | Nonsense Mutation (SNP) | VAF 236/347 reads (68%) | catalogued as COSV100824739; called by muse, mutect2, varscan2
- PLCL2 | c.2518G>A p.E840K (on ENST00000615277 / NM_001144382.2; = p.E714K on NM_015184.5) | Missense Mutation (SNP) | VAF 96/428 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV67626080; called by muse, mutect2, varscan2
- PLXNA4 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 122/429 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58127749; called by muse, mutect2, varscan2
- POLR1A | c.553T>C p.C185R | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs371664576; called by muse, mutect2, varscan2
- POLR1A | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 68/428 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV55689034; called by muse, mutect2, varscan2
- POM121L12 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 215/662 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as rs763758598, COSV68692885; called by muse, mutect2, varscan2
- POU2AF1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 176/311 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as rs866885959; called by muse, mutect2, varscan2
- PPP1R13B | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 204/628 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52449350; called by muse, mutect2, varscan2
- PRB4 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 228/550 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.686); catalogued as COSV54397419; called by muse, mutect2, varscan2
- PRLR | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 163/437 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763133065, COSV99184381; called by muse, mutect2, varscan2
- PROM2 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as rs370908025; called by muse, mutect2, varscan2
- PRR14L | c.5215C>T p.P1739S | Missense Mutation (SNP) | VAF 162/480 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.181); catalogued as rs781139132, COSV57886224; called by muse, mutect2, varscan2
- PTCHD1 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 186/264 reads (70%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV101037964; called by muse, mutect2, varscan2
- PTPRT | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV61974653; called by muse, mutect2, varscan2
- RECK | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 153/219 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as rs777288921; called by muse, mutect2, varscan2
- RNF123 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as rs1279347201; called by muse, mutect2, varscan2
- RYR1 | c.7777C>T p.R2593C | Missense Mutation (SNP) | VAF 159/408 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.99); catalogued as rs756685891, CM112519, COSV62094009; called by muse, mutect2, varscan2
- RYR3 | c.3290G>A p.G1097E | Missense Mutation (SNP) | VAF 180/506 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212405, COSV66777284; called by muse, varscan2
- RYR3 | c.8021C>T p.S2674F (on ENST00000389232; = p.S2675F on NM_001036.6) | Missense Mutation (SNP) | VAF 125/397 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101212142, COSV66808286; called by muse, mutect2, varscan2
- SAMD12 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs989370757; called by muse, mutect2, varscan2
- SCN2A | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768403673, COSV51840549; called by muse, mutect2, varscan2
- SCN8A | c.4660C>T p.L1554F | Missense Mutation (SNP) | VAF 102/459 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100634125; called by muse, mutect2, varscan2
- SEC14L4 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 99/357 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs1283887960, COSV55400368; called by muse, mutect2, varscan2
- SEMA5B | c.2099G>A p.G700D | Missense Mutation (SNP) | VAF 144/414 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755342455; called by muse, mutect2, varscan2
- SIK3 | c.1855C>T p.P619S (on ENST00000445177 / NM_001366686.2; = p.P577S on NM_001281749.3) | Missense Mutation (SNP) | VAF 189/332 reads (57%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.103); catalogued as COSV52615083; called by muse, mutect2, varscan2
- SIPA1L1 | c.2393C>T p.S798L | Missense Mutation (SNP) | VAF 215/420 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs768640690, COSV62173923; called by muse, mutect2, varscan2
- SLC30A3 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 127/291 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51988127; called by muse, mutect2, varscan2
- SLC35F4 | c.767C>T p.S256F (on ENST00000339762 / NM_001352015.2; = p.S220F on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 203/469 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60267591; called by muse, mutect2, varscan2
- SLC36A2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 190/335 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100079457; called by muse, mutect2, varscan2
- SMOC1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 221/503 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs376548937; called by muse, mutect2, varscan2
- SPOCD1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 250/357 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs561311491, COSV57096942; called by muse, mutect2, varscan2
- SPTA1 | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 462/564 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1256527827; called by muse, varscan2
- STAC | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56215858; called by muse, mutect2, varscan2
- STPG2 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.367); catalogued as rs1320469185; called by muse, mutect2, varscan2
- TBX15 | c.1043C>T p.S348F (on ENST00000369429 / NM_001330677.2; = p.S242F on NM_152380.3) | Missense Mutation (SNP) | VAF 208/302 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs377111956; called by muse, mutect2, varscan2
- TEX14 | c.1129C>T p.L377F (on ENST00000240361 / NM_001201457.2; = p.L371F on NM_031272.5) | Missense Mutation (SNP) | VAF 358/473 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs955550746; called by muse, mutect2, varscan2
- THSD7B | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865835196, COSV55672257; called by muse, mutect2, varscan2
- TKTL2 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 169/304 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1480436199; called by muse, mutect2, varscan2
- TNR | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 326/490 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1158312570, COSV54881700; called by muse, mutect2, varscan2
- TPO | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 173/387 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as COSV61099888; called by muse, mutect2, varscan2
- TRRAP | c.7117G>A p.E2373K (on ENST00000359863 / NM_001244580.1; = p.E2355K on NM_003496.3) | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV62842932; called by muse, mutect2, varscan2
- TTN | c.48901G>A p.E16301K (on ENST00000591111; = p.E8877K on NM_003319.4) | Missense Mutation (SNP) | VAF 36/218 reads (17%) | PolyPhen benign (0.033); catalogued as COSV60169071; called by muse, mutect2, varscan2
- TTN | c.28712C>T p.S9571L (on ENST00000591111; = p.S8644L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/250 reads (42%) | PolyPhen benign (0.033); catalogued as COSV60197728; called by muse, mutect2, varscan2
- TTN | c.17482G>A p.E5828K (on ENST00000591111; = p.E4901K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/403 reads (43%) | PolyPhen possibly damaging (0.54); catalogued as rs267599065, COSV60006328; called by muse, mutect2, varscan2
- UBAC2 | c.838C>T p.P280S (on ENST00000403766 / NM_001144072.2; = p.P245S on NM_177967.4) | Missense Mutation (SNP) | VAF 160/275 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.123); catalogued as COSV63122192; called by muse, mutect2, varscan2
- UGT1A5 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 138/342 reads (40%) | catalogued as rs145951104; called by muse, mutect2
- USP10 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.578); catalogued as rs761103695, COSV54753324, COSV99551711; called by muse, mutect2
- UTRN | c.5497C>T p.R1833C | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs751513386, COSV62337547; called by muse, mutect2, varscan2
- VEZT | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 99/367 reads (27%) | catalogued as rs1213729346, COSV99704286; called by muse, mutect2, varscan2
- VMA21 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 206/275 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57757728; called by muse, mutect2, varscan2
- ZBED9 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 184/477 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs866308071, COSV71729246; called by muse, mutect2, varscan2
- ZBTB11 | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs150207556; called by muse, mutect2, varscan2
- ZFR2 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375058331; called by muse, mutect2, varscan2
- ZNF324B | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 106/450 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs1162111156; called by muse, mutect2, varscan2
- ZNF341 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 158/400 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1468761085; called by muse, mutect2, varscan2
- ZNF385B | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1209439769; called by muse, mutect2, varscan2
- ZNF429 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 167/365 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61914863; called by muse, mutect2, varscan2
- A1CF | c.1414G>A p.G472R (on ENST00000373993 / NM_138932.2; = p.G464R on NM_014576.4) | Missense Mutation (SNP) | VAF 180/297 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- AAGAB | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 140/415 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ADAM11 | c.2073C>T p.V691= | Splice Region (SNP) | VAF 211/287 reads (74%) | called by muse, mutect2, varscan2
- ADAM21 | c.1927G>T p.G643W | Missense Mutation (SNP) | VAF 171/631 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL3 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 105/288 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY8 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 85/425 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRG4 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 185/246 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ADNP | c.2687T>A p.V896D | Missense Mutation (SNP) | VAF 172/504 reads (34%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- AL391650.1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 266/389 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ALG10 | c.1080A>T p.K360N | Missense Mutation (SNP) | VAF 121/246 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ALG13 | c.2167C>T p.Q723* | Nonsense Mutation (SNP) | VAF 105/249 reads (42%) | called by muse, mutect2, varscan2
- ALX1 | c.50A>G p.N17S | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMBP | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANK1 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ANKRD30B | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ANKRD31 | c.4822C>T p.Q1608* | Nonsense Mutation (SNP) | VAF 105/209 reads (50%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.2923G>A p.E975K (on ENST00000276826 / NM_001308208.2; = p.E1006K on NM_025251.2) | Missense Mutation (SNP) | VAF 175/418 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- ARRB1 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 126/268 reads (47%) | called by muse, mutect2, varscan2
- ATP1A4 | c.83A>T p.K28I | Missense Mutation (SNP) | VAF 275/384 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ATP2A3 | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 227/353 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP8B4 | c.3548G>A p.S1183N | Missense Mutation (SNP) | VAF 114/226 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- B4GALNT2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 243/325 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- BICRAL | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 149/444 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BPIFB6 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 103/358 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CADM3 | c.121G>A p.V41M (on ENST00000368125 / NM_001127173.3; = p.V75M on NM_021189.5) | Missense Mutation (SNP) | VAF 499/617 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CALU | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 134/329 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAND1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CD80 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC25C | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 82/139 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDH1 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 87/266 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH17 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 84/348 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELSR3 | c.5695G>A p.G1899S | Missense Mutation (SNP) | VAF 244/474 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CEMIP | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 139/404 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CFAP91 | c.1789C>G p.H597D | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHL1 | c.2437C>T p.P813S (on ENST00000397491 / NM_001253387.1; = p.P829S on NM_006614.4) | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC4E | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CMKLR1 | c.29C>T p.T10I (on ENST00000312143 / NM_001142344.2; = p.T8I on NM_004072.3) | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL3A1 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- COL4A6 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 226/314 reads (72%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- CTAGE15 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.386); called by muse, varscan2
- CYP4F22 | c.1025G>A p.S342N | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP4X1 | c.1497G>C p.M499I | Missense Mutation (SNP) | VAF 143/227 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYTH2 | c.899C>T p.P300L (on ENST00000427476; = p.P299L on NM_004228.7) | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DAB2 | c.2057T>C p.F686S | Missense Mutation (SNP) | VAF 71/474 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAG1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 188/456 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DDX43 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DGKI | c.2573T>A p.V858E | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- DIP2C | c.2981G>C p.C994S | Missense Mutation (SNP) | VAF 169/324 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.1482G>A p.W494* (on ENST00000409039; = p.W433* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 83/378 reads (22%) | called by muse, mutect2, varscan2
- DSP | c.2741C>T p.S914F | Missense Mutation (SNP) | VAF 123/381 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- EGF | c.3568C>T p.P1190S | Missense Mutation (SNP) | VAF 183/322 reads (57%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESPL1 | c.5860C>T p.P1954S | Missense Mutation (SNP) | VAF 91/391 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EXOC8 | c.1677A>C p.K559N | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- FAAH2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 159/231 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FAT3 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 137/257 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCHSD2 | c.2103G>T p.R701S | Missense Mutation (SNP) | VAF 74/1078 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- FCHSD2 | c.1552G>C p.G518R | Missense Mutation (SNP) | VAF 60/1042 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FRG2C | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 132/845 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FUT5 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 217/533 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- GAK | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 208/349 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- GBP4 | c.250T>C p.S84P | Missense Mutation (SNP) | VAF 116/193 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- GLRA2 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 201/270 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GP2 | c.578C>T p.A193V (on ENST00000381362 / NM_001007240.3; = p.A190V on NM_001502.4) | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GPR157 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 148/254 reads (58%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GRIN2A | c.4033C>T p.P1345S | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GSR | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- HERC1 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HERC6 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 81/269 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HHIP | c.2012G>A p.R671K | Missense Mutation (SNP) | VAF 161/288 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HNF4A | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 196/513 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- HSPG2 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 237/376 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- IL16 | c.1598C>G p.P533R | Missense Mutation (SNP) | VAF 186/512 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQCE | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 103/351 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IREB2 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 127/383 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAX | c.2672G>A p.G891E | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JPH1 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 75/423 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- KCNJ4 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 144/423 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- KCNK10 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 251/791 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNK16 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNQ3 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 179/383 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNQ3 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LAMA3 | c.3350T>A p.L1117Q | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LCORL | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 150/280 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LIFR | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 126/341 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LIMA1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- LRRK2 | c.2816T>A p.I939N | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LY6G6E | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 155/495 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LYVE1 | c.612A>C p.E204D | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- MAGI2 | c.2765T>C p.V922A | Missense Mutation (SNP) | VAF 79/416 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- MAPK8IP2 | c.2344T>C p.F782L | Missense Mutation (SNP) | VAF 194/473 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MATN4 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 193/585 reads (33%) | PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MBTPS1 | c.905A>T p.D302V | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MEI4 | c.844T>G p.S282A | Missense Mutation (SNP) | VAF 288/502 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MINDY2 | c.631T>G p.L211V | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); called by mutect2, varscan2
- MYO1H | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MYRFL | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 54/317 reads (17%) | called by muse, mutect2, varscan2
- MYRIP | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 135/570 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NCAM2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEB | c.18482G>A p.G6161E | Missense Mutation (SNP) | VAF 96/226 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NETO2 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- NFKBIE | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 219/626 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NOBOX | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 127/398 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NPAP1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 207/489 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- NPIPA5 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- NPIPB11 | c.1843C>T p.H615Y | Missense Mutation (SNP) | VAF 108/444 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NPL | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 262/387 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR2C1 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 157/342 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- NR4A3 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 228/418 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRDE2 | c.1544A>T p.Q515L | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- OCLN | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 154/255 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- ODAM | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- OR10H2 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 92/408 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- OR7G1 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- OXA1L | c.838C>T p.P280S (on ENST00000285848; = p.P220S on NM_005015.5) | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P2RX5 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 168/247 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- P2RY2 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 165/1527 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PADI1 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 233/359 reads (65%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAK6 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 152/303 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPOLA | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PARP14 | c.4157G>A p.R1386K | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PCDHA3 | c.1209T>A p.N403K | Missense Mutation (SNP) | VAF 179/328 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCNX2 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 314/451 reads (70%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PCOLCE2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 68/323 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PCSK5 | c.1110C>T p.I370= | Splice Region (SNP) | VAF 72/142 reads (51%) | called by muse, mutect2, varscan2
- PDE1C | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 118/464 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.174); called by muse, mutect2
- PDGFRB | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 181/324 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PDHX | c.1369G>C p.G457R | Missense Mutation (SNP) | VAF 381/2180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PI16 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 179/525 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PLEKHG4B | c.1327G>A p.E443K (on ENST00000283426; = p.E799K on NM_052909.5) | Missense Mutation (SNP) | VAF 166/536 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- POM121 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 91/477 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- POP1 | c.1652G>T p.S551I | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POTEI | c.2287G>A p.G763S | Missense Mutation (SNP) | VAF 77/303 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPP4R4 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 113/413 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PRAMEF14 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRRT2 | c.879+7C>T | Splice Region (SNP) | VAF 58/202 reads (29%) | called by muse, mutect2, varscan2
- PSMA8 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- PTPN13 | c.3809G>A p.G1270D (on ENST00000411767 / NM_080683.3; = p.G1251D on NM_006264.3) | Missense Mutation (SNP) | VAF 130/240 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- RAB3A | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- RAD1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RALGAPA1 | c.3017C>T p.S1006F | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- RAVER2 | c.934C>G p.P312A | Missense Mutation (SNP) | VAF 88/399 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- RBM33 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 182/663 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- RFX6 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RHOBTB2 | c.616G>C p.A206P | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RNGTT | c.290G>C p.C97S | Missense Mutation (SNP) | VAF 18/568 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- RP1 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 124/330 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- RTN1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 175/579 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTP5 | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 78/552 reads (14%) | called by muse, mutect2
- SCG3 | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 73/122 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- SERPINA3 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 105/343 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SERPINE1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 81/370 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGSM1 | c.3013C>T p.L1005F (on ENST00000400359 / NM_001039948.4; = p.L944F on NM_133454.3) | Missense Mutation (SNP) | VAF 132/339 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A6 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 144/538 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC27A1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 234/511 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC35F6 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 185/439 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC4A10 | c.976C>T p.P326S (on ENST00000446997 / NM_001354461.2; = p.P296S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 119/243 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLITRK3 | c.2150G>A p.G717D | Missense Mutation (SNP) | VAF 94/412 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- SPATA31A1 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 1191/1595 reads (75%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SPEG | c.7804A>T p.T2602S | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SPTA1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 370/431 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, varscan2
- SPTB | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SS18L1 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 236/596 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- STAB2 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 67/354 reads (19%) | called by muse, mutect2, varscan2
- STAB2 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 167/407 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYN3 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- SYT9 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 123/224 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TAF4B | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TAP2 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 252/706 reads (36%) | called by muse, mutect2, varscan2
- TARS1 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 154/453 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TBC1D32 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TFAP2E | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 368/558 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TICRR | c.5702A>G p.K1901R | Missense Mutation (SNP) | VAF 121/346 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- TMCO3 | c.817-15_836del p.X273_splice | Splice Site (DEL) | VAF 72/206 reads (35%) | called by mutect2, pindel, varscan2
- TMEM108 | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 125/342 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM71 | c.637G>A p.A213T (on ENST00000523829 / NM_001382398.1; = p.A194T on NM_144649.3) | Missense Mutation (SNP) | VAF 149/331 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TMPRSS7 | c.517C>T p.L173F (on ENST00000452346; = p.L60F on NM_001042575.2) | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TNC | c.5947G>A p.D1983N | Missense Mutation (SNP) | VAF 128/235 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFRSF25 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 307/447 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TNFRSF4 | c.252C>A p.C84* | Nonsense Mutation (SNP) | VAF 54/262 reads (21%) | called by muse, mutect2, varscan2
- TNNI3K | c.2407C>T p.Q803* | Nonsense Mutation (SNP) | VAF 190/284 reads (67%) | called by muse, mutect2, varscan2
- TOX3 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TPH2 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- TRAV5 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 125/372 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TRIM11 | c.159C>G p.C53W | Missense Mutation (SNP) | VAF 20/796 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM31 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 117/345 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM49B | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 149/263 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRIML2 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 134/282 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPV1 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 207/300 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- TSKU | c.554C>A p.T185N | Missense Mutation (SNP) | VAF 106/344 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTBK1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 97/346 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- TTN | c.86386G>A p.E28796K (on ENST00000591111; = p.E21372K on NM_003319.4) | Missense Mutation (SNP) | VAF 26/193 reads (13%) | PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TUBA3D | c.746A>T p.N249I | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- UBR2 | c.3976C>T p.P1326S | Missense Mutation (SNP) | VAF 120/360 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- UGT1A9 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 135/303 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- USP15 | c.2485C>T p.P829S (on ENST00000280377 / NM_001351159.2; = p.P800S on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/406 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- VRK1 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 151/406 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- WASHC4 | c.2708C>T p.P903L | Missense Mutation (SNP) | VAF 118/322 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- WNT9B | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 495/683 reads (72%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- XIRP1 | c.3982C>T p.P1328S | Missense Mutation (SNP) | VAF 234/490 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBTB22 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 344/950 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ZBTB49 | c.412A>C p.S138R | Missense Mutation (SNP) | VAF 137/254 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZC3HC1 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 113/427 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZDHHC8 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF550 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF570 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 172/391 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF578 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 119/272 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF671 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- ZNF746 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 116/477 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AATK | c.2916C>T p.G972= (on ENST00000326724 / NM_001080395.3; = p.G869= on NM_004920.2) | Silent (SNP) | VAF 252/405 reads (62%) | called by muse, mutect2, varscan2
- ACAN | c.6480G>A p.E2160= | Silent (SNP) | VAF 182/512 reads (36%) | catalogued as rs763519030, COSV61358666; called by muse, mutect2, varscan2
- ACSL1 | c.2008C>T p.L670= | Silent (SNP) | VAF 158/289 reads (55%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.3786A>C p.T1262= | Silent (SNP) | VAF 208/542 reads (38%) | called by muse, mutect2, varscan2
- ADCY5 | c.769T>C p.L257= | Silent (SNP) | VAF 104/425 reads (24%) | catalogued as rs1161460820; called by muse, mutect2, varscan2
- AGBL3 | c.2511G>A p.K837= | Silent (SNP) | VAF 143/338 reads (42%) | catalogued as rs752757788; called by muse, mutect2, varscan2
- AGXT2 | c.855C>T p.F285= | Silent (SNP) | VAF 113/362 reads (31%) | catalogued as rs533299831, COSV51483829; called by muse, mutect2, varscan2
- AHDC1 | c.2847C>T p.P949= | Silent (SNP) | VAF 338/500 reads (68%) | called by muse, mutect2, varscan2
- AHNAK2 | c.4593C>T p.S1531= | Silent (SNP) | VAF 208/603 reads (34%) | catalogued as COSV100317813; called by muse, mutect2
- AL391650.1 | c.21C>T p.T7= | Silent (SNP) | VAF 266/391 reads (68%) | called by muse, mutect2, varscan2
- AMER2 | c.102C>T p.A34= | Silent (SNP) | VAF 234/367 reads (64%) | called by muse, mutect2, varscan2
- ANKRD44 | c.171T>C p.I57= | Silent (SNP) | VAF 36/214 reads (17%) | called by muse, mutect2, varscan2
- ANKRD44 | c.99T>C p.D33= | Silent (SNP) | VAF 38/241 reads (16%) | catalogued as rs1433238292; called by muse, mutect2, varscan2
- ANKRD50 | c.1173C>T p.I391= | Silent (SNP) | VAF 169/280 reads (60%) | catalogued as COSV72386401; called by muse, mutect2, varscan2
- ANO4 | c.729C>T p.I243= (on ENST00000392977 / NM_001286615.2; = p.I208= on NM_178826.4) | Silent (SNP) | VAF 86/217 reads (40%) | catalogued as rs756394333; called by muse, mutect2, varscan2
- ARAP1 | c.1638C>T p.P546= (on ENST00000393609 / NM_001040118.2; = p.P301= on NM_015242.4) | Silent (SNP) | VAF 1011/1374 reads (74%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.4911C>T p.F1637= | Silent (SNP) | VAF 127/284 reads (45%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.319C>T p.L107= | Silent (SNP) | VAF 145/238 reads (61%) | called by muse, mutect2, varscan2
- ARHGEF16 | c.394C>T p.L132= | Silent (SNP) | VAF 325/494 reads (66%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.723T>G p.T241= | Silent (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- ASCC2 | c.1089C>T p.F363= | Silent (SNP) | VAF 163/381 reads (43%) | called by muse, mutect2, varscan2
- ATP13A4 | c.3513C>T p.S1171= | Silent (SNP) | VAF 71/268 reads (26%) | called by muse, mutect2, varscan2
- ATP4A | c.504C>T p.I168= | Silent (SNP) | VAF 164/361 reads (45%) | catalogued as COSV52865491; called by muse, mutect2, varscan2
- ATP7B | c.3876C>T p.I1292= | Silent (SNP) | VAF 254/349 reads (73%) | catalogued as rs978231751; called by muse, mutect2, varscan2
- AVPR1B | c.525G>A p.R175= | Silent (SNP) | VAF 343/511 reads (67%) | catalogued as COSV65638240; called by muse, mutect2, varscan2
- B3GALT5 | c.12G>A p.P4= | Silent (SNP) | VAF 113/237 reads (48%) | catalogued as rs746851790, COSV58198144; called by muse, mutect2, varscan2
- BBOX1 | c.498G>T p.G166= | Silent (SNP) | VAF 132/254 reads (52%) | called by muse, mutect2
- BPIFB4 | c.777G>A p.G259= | Silent (SNP) | VAF 149/369 reads (40%) | catalogued as COSV64950660; called by muse, mutect2, varscan2
- CABP4 | c.712C>T p.L238= | Silent (SNP) | VAF 1217/1490 reads (82%) | called by muse, mutect2, varscan2
- CACNG8 | c.222G>A p.S74= | Silent (SNP) | VAF 96/521 reads (18%) | catalogued as rs1036844702; called by muse, mutect2, varscan2
- CAMTA1 | c.1464C>T p.F488= | Silent (SNP) | VAF 304/475 reads (64%) | catalogued as COSV57921386; called by muse, mutect2, varscan2
- CCDC136 | c.2892C>T p.L964= | Silent (SNP) | VAF 124/451 reads (27%) | called by muse, mutect2, varscan2
- CDC14B | c.516T>C p.S172= | Silent (SNP) | VAF 105/197 reads (53%) | catalogued as rs1021509007; called by muse, mutect2, varscan2
- CDH24 | c.378C>T p.S126= | Silent (SNP) | VAF 207/638 reads (32%) | called by muse, mutect2, varscan2
- CEP170B | c.4743C>T p.F1581= (on ENST00000453495; = p.F1510= on NM_015005.3) | Silent (SNP) | VAF 138/447 reads (31%) | catalogued as rs1016666237; called by muse, mutect2, varscan2
- CEP97 | c.1605G>A p.E535= | Silent (SNP) | VAF 91/304 reads (30%) | called by muse, mutect2, varscan2
- CHL1 | c.2247G>A p.V749= (on ENST00000397491 / NM_001253387.1; = p.V765= on NM_006614.4) | Silent (SNP) | VAF 171/370 reads (46%) | catalogued as rs549419065; called by muse, mutect2, varscan2
- CLINT1 | c.1077C>T p.F359= | Silent (SNP) | VAF 123/218 reads (56%) | called by muse, mutect2, varscan2
- CNBD1 | c.477C>T p.F159= | Silent (SNP) | VAF 58/307 reads (19%) | catalogued as COSV72976839; called by muse, mutect2, varscan2
- CNMD | c.411G>A p.V137= | Silent (SNP) | VAF 195/318 reads (61%) | catalogued as rs201903908; called by muse, mutect2, varscan2
- CNTNAP3 | c.351G>A p.G117= | Silent (SNP) | VAF 56/399 reads (14%) | called by muse, mutect2, varscan2
- COL6A6 | c.3513C>T p.I1171= | Silent (SNP) | VAF 86/264 reads (33%) | catalogued as rs755097067, COSV100650183, COSV62028722; called by muse, mutect2, varscan2
- CPNE3 | c.651T>C p.Y217= | Silent (SNP) | VAF 44/193 reads (23%) | called by muse, mutect2, varscan2
- CYLC1 | c.1392G>A p.G464= | Silent (SNP) | VAF 133/185 reads (72%) | catalogued as COSV61414586; called by muse, mutect2, varscan2
- DDX28 | c.855G>A p.L285= | Silent (SNP) | VAF 64/217 reads (29%) | called by muse, mutect2, varscan2
- DMD | c.3102C>T p.S1034= | Silent (SNP) | VAF 164/244 reads (67%) | called by muse, varscan2
- DNAJA2 | c.1194A>G p.E398= | Silent (SNP) | VAF 67/236 reads (28%) | called by muse, mutect2, varscan2
- EFCAB7 | c.768C>T p.N256= | Silent (SNP) | VAF 136/229 reads (59%) | called by muse, mutect2, varscan2
- ERN2 | c.673C>T p.L225= | Silent (SNP) | VAF 112/369 reads (30%) | catalogued as rs201823597; called by muse, mutect2, varscan2
- EVC2 | c.3741G>A p.E1247= | Silent (SNP) | VAF 73/283 reads (26%) | catalogued as rs768693733; called by muse, mutect2, varscan2
- EYS | c.4053G>A p.L1351= | Silent (SNP) | VAF 149/444 reads (34%) | called by muse, mutect2, varscan2
- FAM47A | c.2031G>A p.R677= | Silent (SNP) | VAF 160/228 reads (70%) | catalogued as COSV60495404; called by muse, mutect2, varscan2
- FAM83H | c.1218C>T p.A406= | Silent (SNP) | VAF 214/473 reads (45%) | called by muse, mutect2, varscan2
- FBXO46 | c.894C>T p.A298= | Silent (SNP) | VAF 171/410 reads (42%) | called by muse, mutect2, varscan2
- FCMR | c.790C>T p.L264= | Silent (SNP) | VAF 293/410 reads (71%) | catalogued as rs1191697261; called by muse, mutect2, varscan2
- FLT1 | c.2475G>A p.E825= | Silent (SNP) | VAF 196/318 reads (62%) | catalogued as rs1333978602; called by muse, mutect2, varscan2
- FPR2 | c.78G>A p.R26= | Silent (SNP) | VAF 87/400 reads (22%) | called by muse, mutect2, varscan2
- FPR2 | c.438C>T p.I146= | Silent (SNP) | VAF 150/369 reads (41%) | catalogued as rs200320548, COSV100389426, COSV60672026; called by muse, mutect2, varscan2
- FREM2 | c.261C>G p.V87= | Silent (SNP) | VAF 16/584 reads (3%) | called by muse, mutect2
- FSIP2 | c.10953G>A p.Q3651= | Silent (SNP) | VAF 43/313 reads (14%) | called by muse, mutect2
- GAD2 | c.1200C>T p.V400= | Silent (SNP) | VAF 105/188 reads (56%) | catalogued as COSV52167682; called by muse, mutect2, varscan2
- GALNT16 | c.699C>T p.T233= | Silent (SNP) | VAF 113/376 reads (30%) | called by muse, mutect2, varscan2
- GASK1A | c.825G>T p.G275= | Silent (SNP) | VAF 222/490 reads (45%) | called by muse, mutect2, varscan2
- GBP1 | c.1053G>A p.Q351= | Silent (SNP) | VAF 320/493 reads (65%) | called by muse, mutect2, varscan2
- GBP4 | c.249C>T p.G83= | Silent (SNP) | VAF 114/191 reads (60%) | called by muse, mutect2, varscan2
- GP2 | c.579C>T p.A193= (on ENST00000381362 / NM_001007240.3; = p.A190= on NM_001502.4) | Silent (SNP) | VAF 64/301 reads (21%) | called by muse, mutect2, varscan2
- GPR45 | c.102G>A p.R34= | Silent (SNP) | VAF 58/388 reads (15%) | catalogued as COSV51522854; called by muse, mutect2, varscan2
- GPR68 | c.900C>T p.L300= | Silent (SNP) | VAF 248/682 reads (36%) | catalogued as rs1359908374; called by muse, mutect2, varscan2
- GRB10 | c.27C>T p.C9= | Silent (SNP) | VAF 152/417 reads (36%) | called by muse, mutect2, varscan2
- GRIK4 | c.1227C>T p.I409= | Silent (SNP) | VAF 141/266 reads (53%) | called by muse, mutect2, varscan2
- GRIN3A | c.1752G>A p.L584= | Silent (SNP) | VAF 140/229 reads (61%) | catalogued as COSV62453839; called by muse, mutect2, varscan2
- GSAP | c.2325C>T p.I775= | Silent (SNP) | VAF 145/353 reads (41%) | called by muse, mutect2, varscan2
- HS3ST5 | c.420G>A p.R140= | Silent (SNP) | VAF 68/272 reads (25%) | catalogued as COSV57150998; called by muse, mutect2, varscan2
- HSPA2 | c.1512C>T p.I504= | Silent (SNP) | VAF 206/439 reads (47%) | called by muse, mutect2, varscan2
- HTR7 | c.588G>A p.G196= | Silent (SNP) | VAF 136/273 reads (50%) | catalogued as COSV53294293; called by muse, mutect2, varscan2
- HYDIN | c.12348C>T p.F4116= | Silent (SNP) | VAF 65/257 reads (25%) | catalogued as rs748124214, COSV66637391; called by muse, mutect2, varscan2
- HYDIN | c.657G>A p.K219= | Silent (SNP) | VAF 38/252 reads (15%) | catalogued as COSV99863093; called by muse, mutect2, varscan2
- IGLV5-45 | c.24C>T p.L8= | Silent (SNP) | VAF 122/406 reads (30%) | called by muse, varscan2
- IL1B | c.565T>C p.L189= | Silent (SNP) | VAF 91/217 reads (42%) | called by muse, mutect2, varscan2
- IMPG1 | c.816G>A p.K272= | Silent (SNP) | VAF 172/316 reads (54%) | called by muse, mutect2, varscan2
- ISM2 | c.417G>A p.R139= | Silent (SNP) | VAF 156/459 reads (34%) | catalogued as COSV53634948, COSV99376608; called by muse, mutect2, varscan2
- KCNH5 | c.2013G>A p.R671= | Silent (SNP) | VAF 61/250 reads (24%) | catalogued as COSV59770839; called by muse, mutect2, varscan2
- KCNK13 | c.876G>A p.R292= | Silent (SNP) | VAF 155/504 reads (31%) | catalogued as COSV56415701; called by muse, mutect2, varscan2
- KDM5A | c.4146A>G p.K1382= | Silent (SNP) | VAF 92/397 reads (23%) | called by muse, mutect2, varscan2
- KIAA1549 | c.1458C>T p.P486= | Silent (SNP) | VAF 67/270 reads (25%) | catalogued as rs773356951; called by muse, mutect2
- KIF3B | c.1269T>A p.I423= | Silent (SNP) | VAF 208/524 reads (40%) | called by muse, varscan2
- KIF6 | c.2073C>T p.T691= | Silent (SNP) | VAF 141/340 reads (41%) | called by muse, mutect2, varscan2
- KLF18 | c.1533G>A p.Q511= | Silent (SNP) | VAF 299/489 reads (61%) | called by muse, varscan2
- KMT2D | c.9279C>T p.P3093= | Silent (SNP) | VAF 192/421 reads (46%) | called by muse, mutect2, varscan2
- KNTC1 | c.5196C>T p.A1732= | Silent (SNP) | VAF 53/256 reads (21%) | catalogued as rs1301232683; called by muse, mutect2, varscan2
- KRR1 | c.318G>A p.K106= | Silent (SNP) | VAF 78/393 reads (20%) | catalogued as COSV56990310; called by muse, mutect2, varscan2
- KYNU | c.1245C>T p.F415= | Silent (SNP) | VAF 80/177 reads (45%) | called by muse, mutect2, varscan2
- LAMA1 | c.5349C>A p.L1783= | Silent (SNP) | VAF 127/324 reads (39%) | called by muse, mutect2, varscan2
- LOXL1 | c.1444C>T p.L482= | Silent (SNP) | VAF 173/562 reads (31%) | called by muse, mutect2, varscan2
- LRP1B | c.11325C>T p.I3775= | Silent (SNP) | VAF 127/286 reads (44%) | catalogued as rs779468925; called by muse, mutect2, varscan2
- LRTM1 | c.1035C>T p.A345= | Silent (SNP) | VAF 85/189 reads (45%) | called by muse, mutect2, varscan2
- LY75 | c.4518G>A p.K1506= | Silent (SNP) | VAF 20/173 reads (12%) | catalogued as rs142810241, COSV55110461; called by muse, mutect2, varscan2
- LYPLA1 | c.147C>T p.I49= | Silent (SNP) | VAF 44/306 reads (14%) | catalogued as COSV57604391; called by muse, mutect2, varscan2
- MAG | c.1380C>T p.F460= | Silent (SNP) | VAF 209/455 reads (46%) | catalogued as rs148978165, COSV62699973; called by muse, mutect2, varscan2
- MBD3L2 | c.483C>T p.L161= | Silent (SNP) | VAF 95/523 reads (18%) | called by muse, mutect2, varscan2
- MFSD8 | c.483C>T p.S161= | Silent (SNP) | VAF 91/183 reads (50%) | called by muse, mutect2, varscan2
- MGAM | c.666G>A p.Q222= | Silent (SNP) | VAF 105/380 reads (28%) | catalogued as COSV101516346; called by muse, mutect2, varscan2
- MGAM | c.4962C>T p.F1654= | Silent (SNP) | VAF 137/419 reads (33%) | catalogued as COSV72073872; called by muse, mutect2, varscan2
- MISP | c.510C>T p.P170= | Silent (SNP) | VAF 105/524 reads (20%) | called by muse, mutect2
- MUC16 | c.36894G>T p.V12298= | Silent (SNP) | VAF 114/270 reads (42%) | catalogued as COSV67453133; called by muse, mutect2, varscan2
- MUC2 | c.498C>T p.F166= | Silent (SNP) | VAF 123/242 reads (51%) | catalogued as rs761363699; called by muse, mutect2, varscan2
- MXRA5 | c.6336C>T p.L2112= | Silent (SNP) | VAF 261/355 reads (74%) | catalogued as rs1432139914, COSV54242051; called by muse, mutect2, varscan2
- NCLN | c.1125C>T p.F375= | Silent (SNP) | VAF 176/422 reads (42%) | catalogued as rs757387758, COSV55742830; called by muse, mutect2, varscan2
- NCR3LG1 | c.1329C>T p.S443= | Silent (SNP) | VAF 129/253 reads (51%) | catalogued as rs1260895305; called by muse, mutect2, varscan2
- NISCH | c.399C>T p.L133= | Silent (SNP) | VAF 162/381 reads (43%) | catalogued as COSV61902992; called by muse, mutect2, varscan2
- NLRP7 | c.2046G>A p.V682= (on ENST00000340844 / NM_206828.3; = p.V654= on NM_139176.3) | Silent (SNP) | VAF 105/571 reads (18%) | catalogued as rs993360162, COSV60182187; called by muse, mutect2, varscan2
- NMRK1 | c.15C>T p.I5= | Silent (SNP) | VAF 70/154 reads (45%) | catalogued as rs538581583; called by muse, mutect2, varscan2
- NNMT | c.204C>T p.I68= | Silent (SNP) | VAF 162/273 reads (59%) | called by muse, mutect2, varscan2
- NOSTRIN | c.1446G>T p.G482= (on ENST00000317647 / NM_001039724.4; = p.G404= on NM_052946.3) | Silent (SNP) | VAF 130/275 reads (47%) | catalogued as rs373131496; called by muse, mutect2, varscan2
- NOTCH3 | c.6675G>A p.G2225= | Silent (SNP) | VAF 105/491 reads (21%) | called by muse, mutect2, varscan2
- NPAP1 | c.921T>A p.P307= | Silent (SNP) | VAF 131/354 reads (37%) | called by muse, mutect2, varscan2
- NPHP4 | c.2268C>T p.S756= | Silent (SNP) | VAF 238/358 reads (66%) | catalogued as rs768290484; called by muse, mutect2, varscan2
- NRK | c.3795C>T p.I1265= | Silent (SNP) | VAF 76/110 reads (69%) | called by muse, mutect2, varscan2
- OPN5 | c.597C>T p.F199= | Silent (SNP) | VAF 198/512 reads (39%) | called by muse, mutect2, varscan2
- OR2T5 | c.351C>T p.F117= | Silent (SNP) | VAF 111/302 reads (37%) | called by muse, mutect2, varscan2
- OR4F17 | c.58C>T p.L20= | Silent (SNP) | VAF 103/1306 reads (8%) | called by muse, mutect2
- OR51A4 | c.315C>T p.F105= | Silent (SNP) | VAF 177/360 reads (49%) | catalogued as COSV100985229, COSV66749283; called by muse, mutect2, varscan2
- OR56A4 | c.207C>A p.L69= | Silent (SNP) | VAF 175/341 reads (51%) | catalogued as rs1439174320, COSV58109760; called by muse, mutect2, varscan2
- OR7G2 | c.1030C>T p.L344= | Silent (SNP) | VAF 57/245 reads (23%) | catalogued as COSV59687627; called by muse, mutect2, varscan2
- OTOGL | c.5919C>T p.D1973= (on ENST00000547103; = p.D1964= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 117/236 reads (50%) | catalogued as rs765805043; called by muse, mutect2, varscan2
- P2RY6 | c.972G>A p.Q324= | Silent (SNP) | VAF 581/774 reads (75%) | catalogued as rs1288253943; called by muse, mutect2, varscan2
- PCDHA1 | c.687G>C p.L229= | Silent (SNP) | VAF 18/394 reads (5%) | called by muse, mutect2
- PCDHGA8 | c.1479G>A p.E493= | Silent (SNP) | VAF 203/358 reads (57%) | catalogued as rs1173905383; called by muse, mutect2, varscan2
- PCDHGB1 | c.1344C>T p.F448= | Silent (SNP) | VAF 181/319 reads (57%) | catalogued as COSV53907546, COSV53930784; called by muse, mutect2, varscan2
- PCOLCE | c.427C>T p.L143= | Silent (SNP) | VAF 97/353 reads (27%) | called by muse, mutect2, varscan2
- PDZD2 | c.666C>T p.I222= | Silent (SNP) | VAF 176/517 reads (34%) | called by muse, mutect2, varscan2
- PGK2 | c.732C>T p.F244= | Silent (SNP) | VAF 130/394 reads (33%) | catalogued as rs868318753, COSV59164120; called by muse, varscan2
- PHF2 | c.936C>T p.T312= | Silent (SNP) | VAF 111/198 reads (56%) | catalogued as COSV63681713; called by muse, mutect2, varscan2
- PI16 | c.306C>T p.A102= | Silent (SNP) | VAF 159/478 reads (33%) | called by muse, varscan2
- PIWIL4 | c.72C>T p.I24= | Silent (SNP) | VAF 120/230 reads (52%) | called by muse, mutect2, varscan2
- PLA2G4F | c.2271C>T p.S757= | Silent (SNP) | VAF 221/415 reads (53%) | called by muse, mutect2, varscan2
- PLEKHD1 | c.1164G>A p.K388= | Silent (SNP) | VAF 225/516 reads (44%) | called by muse, mutect2, varscan2
- PLIN5 | c.976C>T p.L326= | Silent (SNP) | VAF 104/413 reads (25%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4347C>T p.F1449= | Silent (SNP) | VAF 72/269 reads (27%) | catalogued as rs533114998; called by muse, mutect2, varscan2
- POTEC | c.864G>A p.V288= | Silent (SNP) | VAF 45/169 reads (27%) | catalogued as COSV100743906, COSV62802483; called by muse, mutect2, varscan2
- PPP1R12C | c.615C>T p.L205= | Silent (SNP) | VAF 98/447 reads (22%) | catalogued as rs370308071; called by muse, mutect2, varscan2
- PPP1R13L | c.1341C>T p.P447= | Silent (SNP) | VAF 88/188 reads (47%) | called by muse, mutect2, varscan2
- PREX1 | c.4941C>T p.L1647= | Silent (SNP) | VAF 169/469 reads (36%) | called by muse, mutect2, varscan2
- PSD4 | c.750C>G p.L250= | Silent (SNP) | VAF 61/386 reads (16%) | called by muse, mutect2
- PTPRC | c.444C>A p.V148= | Silent (SNP) | VAF 225/297 reads (76%) | called by muse, mutect2, varscan2
- PTPRF | c.2730C>T p.T910= | Silent (SNP) | VAF 286/433 reads (66%) | called by muse, mutect2, varscan2
- PTPRK | c.3195G>A p.R1065= (on ENST00000368215 / NM_001291984.2; = p.R1066= on NM_002844.4) | Silent (SNP) | VAF 67/478 reads (14%) | catalogued as rs767089578; called by muse, mutect2, varscan2
- PTPRM | c.1947C>T p.F649= | Silent (SNP) | VAF 171/394 reads (43%) | called by muse, mutect2, varscan2
- PTPRQ | c.4494C>T p.I1498= (on ENST00000616559; = p.I1456= on NM_001145026.2) | Silent (SNP) | VAF 70/328 reads (21%) | called by muse, mutect2, varscan2
- RAB11FIP2 | c.498G>A p.K166= | Silent (SNP) | VAF 19/307 reads (6%) | called by muse, mutect2
- RAB11FIP3 | c.1951C>T p.L651= | Silent (SNP) | VAF 118/453 reads (26%) | called by muse, mutect2, varscan2
- RENBP | c.300C>T p.F100= | Silent (SNP) | VAF 152/232 reads (66%) | called by muse, mutect2, varscan2
- RGMA | c.1095G>A p.K365= | Silent (SNP) | VAF 219/588 reads (37%) | called by muse, mutect2, varscan2
- RIPOR3 | c.768C>T p.I256= | Silent (SNP) | VAF 111/328 reads (34%) | catalogued as COSV99245927; called by muse, mutect2, varscan2
- RNF123 | c.1650C>T p.P550= | Silent (SNP) | VAF 74/218 reads (34%) | catalogued as rs369187602; called by muse, mutect2, varscan2
- RNF152 | c.405C>T p.I135= | Silent (SNP) | VAF 86/416 reads (21%) | catalogued as COSV57187305; called by muse, mutect2
- RNF215 | c.447C>T p.F149= | Silent (SNP) | VAF 124/406 reads (31%) | catalogued as rs773978641; called by muse, mutect2
- RTN2 | c.1374C>T p.S458= | Silent (SNP) | VAF 69/366 reads (19%) | called by muse, mutect2, varscan2
- RXFP3 | c.516C>T p.F172= | Silent (SNP) | VAF 236/638 reads (37%) | catalogued as rs1385472139, COSV57508208; called by muse, mutect2, varscan2
- RYR3 | c.12669G>A p.K4223= (on ENST00000389232; = p.K4224= on NM_001036.6) | Silent (SNP) | VAF 152/422 reads (36%) | catalogued as COSV101212652; called by muse, mutect2, varscan2
- SALL3 | c.1695C>T p.S565= | Silent (SNP) | VAF 330/816 reads (40%) | catalogued as rs758878866, COSV73306598; called by muse, mutect2, varscan2
- SCML4 | c.948G>A p.T316= | Silent (SNP) | VAF 95/245 reads (39%) | catalogued as rs751556399, COSV64638566; called by muse, mutect2, varscan2
- SCN1A | c.5271G>A p.G1757= (on ENST00000303395 / NM_001202435.3; = p.G1746= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/381 reads (16%) | catalogued as COSV57662134; called by muse, mutect2, varscan2
- SCN3A | c.2403G>A p.G801= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as COSV51814908; called by muse, mutect2, varscan2
- SELP | c.90C>A p.I30= | Silent (SNP) | VAF 171/226 reads (76%) | called by muse, mutect2, varscan2
- SERPINA10 | c.645G>A p.G215= | Silent (SNP) | VAF 234/545 reads (43%) | catalogued as rs367966236; called by muse, mutect2, varscan2
- SHANK2 | c.4662C>T p.P1554= | Silent (SNP) | VAF 1704/2074 reads (82%) | catalogued as rs1555152976, COSV99575441; called by muse, mutect2, varscan2
- SHANK2 | c.693G>A p.G231= | Silent (SNP) | VAF 140/1872 reads (7%) | catalogued as COSV58350544; called by muse, mutect2
- SHLD2 | c.2316C>T p.S772= | Silent (SNP) | VAF 72/133 reads (54%) | catalogued as rs1250237463; called by muse, mutect2, varscan2
- SIGLEC7 | c.1089C>T p.A363= | Silent (SNP) | VAF 137/325 reads (42%) | catalogued as rs576616555, COSV58314441; called by muse, mutect2, varscan2
- SLC16A6 | c.837G>A p.K279= | Silent (SNP) | VAF 254/378 reads (67%) | called by muse, mutect2, varscan2
- SLC25A25 | c.1377C>T p.N459= | Silent (SNP) | VAF 177/296 reads (60%) | catalogued as COSV66086119; called by muse, mutect2, varscan2
- SLC3A1 | c.1956G>A p.T652= | Silent (SNP) | VAF 47/269 reads (17%) | catalogued as rs780821343, COSV53218079; called by muse, mutect2, varscan2
- SLC4A11 | c.2589C>T p.I863= | Silent (SNP) | VAF 124/345 reads (36%) | catalogued as rs555765616; called by muse, mutect2, varscan2
- SPPL2C | c.1525C>T p.L509= | Silent (SNP) | VAF 655/880 reads (74%) | catalogued as COSV61292885; called by muse, mutect2, varscan2
- SPTB | c.183G>A p.T61= | Silent (SNP) | VAF 141/463 reads (30%) | catalogued as rs149102226; called by muse, mutect2, varscan2
- SPTBN1 | c.3057G>C p.A1019= | Silent (SNP) | VAF 79/428 reads (18%) | catalogued as COSV61685361; called by muse, mutect2, varscan2
- ST18 | c.2568C>T p.S856= | Silent (SNP) | VAF 191/446 reads (43%) | catalogued as COSV52494876; called by muse, mutect2, varscan2
- STK11IP | c.315C>T p.F105= | Silent (SNP) | VAF 59/308 reads (19%) | called by muse, mutect2, varscan2
- SUPT5H | c.2703C>T p.S901= | Silent (SNP) | VAF 109/531 reads (21%) | catalogued as rs1275364579, COSV63239692; called by muse, mutect2, varscan2
- SYNE3 | c.2850C>T p.D950= | Silent (SNP) | VAF 241/539 reads (45%) | catalogued as COSV62080057; called by muse, mutect2, varscan2
- TBC1D8 | c.1743C>T p.A581= | Silent (SNP) | VAF 43/330 reads (13%) | catalogued as rs1193954937, COSV65215043; called by muse, mutect2, varscan2
- THEMIS | c.912G>A p.G304= | Silent (SNP) | VAF 85/381 reads (22%) | catalogued as COSV100965336; called by muse, mutect2, varscan2
- TMEM185B | c.369C>T p.S123= | Silent (SNP) | VAF 154/392 reads (39%) | called by muse, mutect2, varscan2
- TMEM61 | c.369C>T p.T123= | Silent (SNP) | VAF 143/215 reads (67%) | called by muse, varscan2
- TMPRSS11A | c.112C>T p.L38= | Silent (SNP) | VAF 99/168 reads (59%) | catalogued as rs1474840621, COSV100602746; called by muse, mutect2, varscan2
- TNFRSF13B | c.564G>A p.K188= | Silent (SNP) | VAF 290/453 reads (64%) | called by muse, mutect2, varscan2
- TOX3 | c.1011C>T p.A337= | Silent (SNP) | VAF 40/168 reads (24%) | catalogued as COSV99568279; called by muse, mutect2, varscan2
- TRAPPC8 | c.2302C>T p.L768= | Silent (SNP) | VAF 86/274 reads (31%) | called by muse, mutect2, varscan2
- TREML2 | c.711C>T p.T237= | Silent (SNP) | VAF 163/534 reads (31%) | called by muse, mutect2, varscan2
- TRGV1 | c.78G>A p.T26= | Silent (SNP) | VAF 161/434 reads (37%) | catalogued as rs554554658; called by muse, mutect2, varscan2
- TTN | c.74856C>T p.D24952= (on ENST00000591111; = p.D17528= on NM_003319.4) | Silent (SNP) | VAF 41/331 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.29556G>A p.T9852= (on ENST00000591111; = p.T8925= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/278 reads (15%) | catalogued as rs376088498; called by muse, mutect2, varscan2
- UBASH3A | c.1716C>T p.I572= | Silent (SNP) | VAF 216/388 reads (56%) | catalogued as rs754521940, COSV52312577; called by muse, mutect2, varscan2
- UBE2NL | c.27C>T p.I9= | Silent (SNP) | VAF 117/171 reads (68%) | called by muse, mutect2, varscan2
- UGT1A5 | c.771C>T p.F257= | Silent (SNP) | VAF 136/343 reads (40%) | called by muse, mutect2
- UNKL | c.1578C>T p.S526= | Silent (SNP) | VAF 100/367 reads (27%) | catalogued as rs1162742912, COSV50189815; called by muse, mutect2, varscan2
- USH1G | c.1293C>T p.V431= | Silent (SNP) | VAF 376/541 reads (70%) | called by muse, mutect2, varscan2
- VWF | c.4554G>A p.K1518= | Silent (SNP) | VAF 162/335 reads (48%) | called by muse, mutect2, varscan2
- ZNF16 | c.1509C>T p.A503= | Silent (SNP) | VAF 108/485 reads (22%) | catalogued as rs139626568; called by muse, mutect2, varscan2
- ZNF2 | c.99C>T p.P33= | Silent (SNP) | VAF 105/257 reads (41%) | called by muse, mutect2, varscan2
- ZNF653 | c.891C>T p.P297= | Silent (SNP) | VAF 178/422 reads (42%) | catalogued as rs778197256; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148305 G>A | 5'Flank (SNP) | VAF 70/206 reads (34%) | catalogued as rs745608243; called by muse, mutect2, varscan2
- AL163540.1 | n.103T>C | RNA (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*1076C>T | 3'UTR (SNP) | VAF 140/1418 reads (10%) | catalogued as COSV100354662, COSV57383951; called by muse, mutect2
- ASB10 | chr7:151187591 G>A | 5'Flank (SNP) | VAF 254/582 reads (44%) | catalogued as COSV51997825; called by muse, mutect2, varscan2
- ATP2B2 | c.*69C>T | 3'UTR (SNP) | VAF 48/250 reads (19%) | catalogued as COSV59495188; called by muse, mutect2, varscan2
- ATP2B2 | c.*68C>T | 3'UTR (SNP) | VAF 47/246 reads (19%) | catalogued as COSV100659963; called by muse, mutect2, varscan2
- C2CD6 | c.1582-3481A>G | Intron (SNP) | VAF 30/227 reads (13%) | called by muse, mutect2, varscan2
- CHST15 | c.1347+156T>C | Intron (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- CRAT | c.291+174C>T | Intron (SNP) | VAF 79/155 reads (51%) | called by muse, mutect2, varscan2
- CRHR2 | chr7:30686399 G>A | 5'Flank (SNP) | VAF 127/328 reads (39%) | catalogued as rs561949444, COSV59264623; called by muse, mutect2, varscan2
- DCHS2 | n.8551C>A | RNA (SNP) | VAF 191/355 reads (54%) | catalogued as COSV61768676; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7458C>T | Intron (SNP) | VAF 148/275 reads (54%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+15688C>T | Intron (SNP) | VAF 87/170 reads (51%) | called by muse, mutect2, varscan2
- KRT78 | c.385-141C>T | Intron (SNP) | VAF 68/325 reads (21%) | called by muse, mutect2, varscan2
- MECOM | c.-60G>A | 5'UTR (SNP) | VAF 55/217 reads (25%) | catalogued as COSV52960571; called by muse, mutect2, varscan2
- PRM2 | c.-50C>T | 5'UTR (SNP) | VAF 89/378 reads (24%) | called by muse, mutect2, varscan2
- SMTN | c.51+1845G>C | Intron (SNP) | VAF 229/600 reads (38%) | called by muse, mutect2, varscan2
- TINAG | chr6:54308083 C>T | 5'Flank (SNP) | VAF 140/391 reads (36%) | catalogued as rs866938321; called by muse, mutect2, varscan2
- TREM1 | c.599+16C>T | Intron (SNP) | VAF 138/477 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.10360+1908C>T | Intron (SNP) | VAF 86/182 reads (47%) | called by muse, mutect2
- XIRP2 | c.*114G>A | 3'UTR (SNP) | VAF 75/196 reads (38%) | catalogued as rs1368709934, COSV54719837; called by muse, mutect2, varscan2
- XIRP2 | c.*444C>T | 3'UTR (SNP) | VAF 49/348 reads (14%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26675155 C>T | 3'Flank (SNP) | VAF 127/366 reads (35%) | called by muse, mutect2, varscan2
